Gene-level copy-number profile of tumor specimen C3N-02586-01 (profiled together with C3N-02586-02) from CPTAC case C3N-02586, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 74.0 years (27,040 days).
Specimen C3N-02586-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e3c53c17-1716-4798-b94e-56f66385ea22.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02586-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/dc7b9d4c-ea01-4171-988e-468af38c89df

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 556; copy number 1: 51,991; copy number 2: 3,128; copy number 3: 1,464; copy number 4: 1,720; copy number 5: 14; copy number 7: 5.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.
- chr1:248,573,801–248,635,091, 5 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:27,890,315–27,912,396, 5 genes: H3C12, H2AC17, H2BC17, RNU7-26P, OR2B2.
- chr6:29,887,294–29,929,232, 7 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr21:8,603,547–8,680,934, 2 genes: RPSAP68, CR381572.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,203 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 4 (broad region; genes not listed).
- chr7:70,972–63,263,456, 1,046 genes, copy number 4–7 (broad region; genes not listed).
- chr7:63,377,329–63,385,789, 2 genes, copy number 3: VN1R32P, AC073188.3.
- chr8:51,899,268–145,066,685, 1,414 genes, copy number 3 (broad region; genes not listed).
- chr10:48,009,873–48,031,640, 1 gene, copy number 3: AGAP12P.
- chr15:21,328,380–22,059,831, 41 genes, copy number 3 (within-gene range 1–3): AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,083,221, 1 gene, copy number 3: OR4M2.
- chr16:32,356,981–32,380,049, 2 genes, copy number 5: AC133548.1, ACTR3BP3.
- chr16:32,454,612–32,460,362, 2 genes, copy number 3: AC138915.3, AC138915.1.
- chr19:43,192,702–43,269,530, 3 genes, copy number 3: PSG4, CEACAMP10, PSG9.
- chr22:18,400,407–18,611,919, 12 genes, copy number 5: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.

Autosomal genes at a single copy (total copy number 1): 50,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
